Somatic mutation profile of tumor specimen MMRF_2843_1_BM_CD138pos (aliquot MMRF_2843_1_BM_CD138pos_T1_KHS5U_L16571) from MMRF case MMRF_2843, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.9 years (16,767 days).
Specimen MMRF_2843_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ffbcf89-bd69-4147-874d-8f681225b664.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2843_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2843_1_PB_WBC_C2_KHS5U_L16669; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/faa92570-e9d1-42fb-b1fb-2e2dfa0ee4f1

The open-access MAF lists 145 somatic variants for this specimen: 60 protein-altering or splice-affecting, 27 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, 3'UTR 27, Silent 27, Intron 14, 5'UTR 8, 3'Flank 4, Frame Shift Del 3, Splice Site 3, Nonsense Mutation 3, 5'Flank 3, Splice Region 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.6686_6687del p.R2229Kfs*8 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs1557946331; called by mutect2, pindel, varscan2
- CACNA1G | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 93/367 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs750533742; called by muse, mutect2, varscan2
- CASP4 | c.1001C>G p.S334C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV67744337; called by muse, varscan2
- CDH26 | c.2126C>T p.A709V (on ENST00000348616 / NM_177980.4; = p.A42V on NM_021810.6) | Missense Mutation (SNP) | VAF 56/95 reads (59%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs751056503; called by muse, mutect2, varscan2
- CELF6 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 152/465 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs769547615, COSV54715476; called by muse, mutect2, varscan2
- DNAI1 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV54284812; called by muse, mutect2, varscan2
- EPPK1 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 120/184 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs150196045; called by muse, mutect2
- FLNC | c.3166G>A p.G1056S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1287987501; called by muse, mutect2, varscan2
- HHIP | c.629+1G>T p.X210_splice | Splice Site (SNP) | VAF 37/61 reads (61%) | catalogued as COSV56841480; called by muse, mutect2, varscan2
- IGHV2-70 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/8 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs534553794; called by mutect2, varscan2
- IGKV4-1 | c.290T>A p.F97Y | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs72847570; called by muse, varscan2
- IGLL5 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.087); catalogued as rs777349722, COSV73249535, COSV73250343, COSV73250409; called by muse, varscan2
- IGLL5 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.84); catalogued as rs760680162; called by muse, mutect2, varscan2
- IGLON5 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760643094, COSV54534379; called by muse, varscan2
- IGLV6-57 | c.153C>G p.N51K | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs555174032; called by muse, varscan2
- KLRG2 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs1194719207; called by muse, mutect2, varscan2
- LNX2 | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs993110444; called by muse, mutect2, varscan2
- MAK16 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.26); catalogued as rs370935181, COSV100789433; called by muse, mutect2, varscan2
- PDX1 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs901280387; called by muse, mutect2, varscan2
- PRAMEF12 | c.743T>G p.L248R | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.185); catalogued as COSV63214644, COSV63215980; called by muse, mutect2, varscan2
- REPIN1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 104/176 reads (59%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs1203669495; called by muse, mutect2, varscan2
- SDK1 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs776052768, COSV67356197; called by muse, mutect2, varscan2
- TANK | c.208+1G>A p.X70_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as rs1190545652, COSV52045250; called by mutect2, varscan2
- TBC1D4 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs1002796555; called by muse, mutect2, varscan2
- TRIM46 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs866560615, COSV55279009, COSV55280426; called by muse, mutect2, varscan2
- ABCA7 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- AFF3 | c.1286A>T p.E429V | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ATP5F1A | c.1046T>C p.L349P | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLCN7 | c.1884-16_1891del p.X628_splice | Splice Site (DEL) | VAF 21/52 reads (40%) | called by mutect2, pindel, varscan2
- COL6A3 | c.7082C>A p.P2361Q | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CR589904.2 | c.*47-3C>T | Splice Region (SNP) | VAF 68/81 reads (84%) | called by muse, mutect2, varscan2
- DST | c.20188G>T p.E6730* (on ENST00000361203 / NM_001374722.1; = p.E4427* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- FAM222A | c.586del p.L196Cfs*72 | Frame Shift Del (DEL) | VAF 65/117 reads (56%) | called by mutect2, varscan2
- GFRAL | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GRM5 | c.1853G>A p.C618Y | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXC12 | c.329A>T p.E110V | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HTR1A | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- HUS1B | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- IGHV2-70D | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 61/65 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, varscan2
- IGLL5 | c.34A>C p.T12P | Missense Mutation (SNP) | VAF 45/48 reads (94%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.212); called by muse, varscan2
- IL13RA1 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- KIF20A | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- LIN7C | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- LPO | c.444-7G>A | Splice Region (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- NOTCH3 | c.3143G>C p.G1048A | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PDZD2 | c.735C>A p.D245E | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- PPM1N | c.596A>G p.D199G | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PRRT1 | c.238_266del p.T80Sfs*388 | Frame Shift Del (DEL) | VAF 24/51 reads (47%) | called by mutect2, pindel
- PSD3 | c.1556G>A p.S519N | Missense Mutation (SNP) | VAF 71/82 reads (87%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RAB3GAP2 | c.540G>T p.L180F | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- RDH14 | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RIOK1 | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 59/91 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SLC24A2 | c.1766T>C p.V589A | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by mutect2, varscan2
- SLC6A12 | c.1817T>G p.I606R | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TBC1D4 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCEAL7 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, varscan2
- TRIM58 | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TTN | c.10093C>T p.Q3365* (on ENST00000591111; = p.Q3319* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 65/148 reads (44%) | called by muse, mutect2, varscan2
- VPS51 | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ZFC3H1 | c.4647T>G p.N1549K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ASB13 | c.309C>T p.L103= | Silent (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- BCORL1 | c.4029G>A p.G1343= | Silent (SNP) | VAF 30/47 reads (64%) | called by muse, mutect2, varscan2
- BMERB1 | c.561G>A p.T187= | Silent (SNP) | VAF 58/115 reads (50%) | catalogued as rs776720007, COSV100253225, COSV55507228; called by muse, mutect2, varscan2
- CCDC166 | c.448C>T p.L150= | Silent (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- CDS2 | c.810T>A p.T270= | Silent (SNP) | VAF 62/174 reads (36%) | called by muse, mutect2, varscan2
- CPAMD8 | c.3873G>A p.Q1291= (on ENST00000651564; = p.Q1244= on NM_015692.5) | Silent (SNP) | VAF 43/192 reads (22%) | catalogued as rs757514673; called by muse, mutect2, varscan2
- DLX5 | c.549C>T p.I183= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1049250299, COSV56034613; called by muse, mutect2, varscan2
- FRAS1 | c.2427C>T p.C809= | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, varscan2
- GPSM2 | c.85T>C p.L29= | Silent (SNP) | VAF 36/91 reads (40%) | called by muse, mutect2, varscan2
- H2AC4 | c.12C>G p.R4= | Silent (SNP) | VAF 216/354 reads (61%) | called by muse, varscan2
- IGLL5 | c.186C>T p.S62= | Silent (SNP) | VAF 14/14 reads (100%) | catalogued as rs554734650, COSV73251120, COSV73251223; called by muse, mutect2, varscan2
- IGLV3-1 | c.255T>A p.S85= | Silent (SNP) | VAF 98/103 reads (95%) | called by muse, mutect2, varscan2
- IGLV3-25 | c.195G>A p.V65= | Silent (SNP) | VAF 67/153 reads (44%) | catalogued as rs373218624; called by muse, mutect2, varscan2
- MSX1 | c.342G>A p.P114= | Silent (SNP) | VAF 83/158 reads (53%) | catalogued as rs1467749786; called by muse, mutect2, varscan2
- NKX2-4 | c.261G>A p.A87= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1466274317; called by mutect2, varscan2
- NOX1 | c.1428A>G p.G476= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99471502; called by mutect2, varscan2
- NPAS1 | c.585G>A p.L195= | Silent (SNP) | VAF 52/151 reads (34%) | catalogued as rs1414644501; called by muse, mutect2, varscan2
- PAX3 | c.1236C>T p.L412= | Silent (SNP) | VAF 45/74 reads (61%) | catalogued as rs762446077; called by muse, mutect2, varscan2
- PCDH9 | c.3030C>T p.T1010= | Silent (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- PEX11G | c.540G>A p.S180= | Silent (SNP) | VAF 105/226 reads (46%) | catalogued as rs1037409827, COSV55537957; called by muse, mutect2, varscan2
- SCN11A | c.255C>T p.Y85= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs1325213488; called by muse, mutect2, varscan2
- SERINC5 | c.489C>T p.F163= | Silent (SNP) | VAF 43/152 reads (28%) | called by muse, mutect2, varscan2
- SULT1A2 | c.126C>T p.L42= | Silent (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- SYBU | c.1503G>A p.E501= (on ENST00000276646 / NM_001099754.2; = p.E500= on NM_017786.6) | Silent (SNP) | VAF 88/192 reads (46%) | catalogued as COSV52617976; called by muse, varscan2
- SYBU | c.1449G>T p.V483= (on ENST00000276646 / NM_001099754.2; = p.V482= on NM_017786.6) | Silent (SNP) | VAF 88/198 reads (44%) | called by muse, varscan2
- UBN1 | c.1569G>T p.L523= | Silent (SNP) | VAF 22/54 reads (41%) | called by muse, varscan2
- USP43 | c.2946C>A p.R982= | Silent (SNP) | VAF 107/213 reads (50%) | called by muse, mutect2, varscan2
- ABTB1 | c.56+112T>A | Intron (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2
- AL358333.1 | chr14:51979284 G>T | 3'Flank (SNP) | VAF 32/94 reads (34%) | catalogued as rs113328422; called by muse, mutect2, varscan2
- ANKS1B | c.2420-638G>C | Intron (SNP) | VAF 6/174 reads (3%) | called by muse, mutect2
- ATP5PO | c.441+528G>A | Intron (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- BEND2 | c.-71C>T | 5'UTR (SNP) | VAF 72/136 reads (53%) | called by muse, mutect2, varscan2
- C10orf67 | c.*1009G>T | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- CACNA1E | c.*6926G>C | 3'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81948158 T>A | 3'Flank (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2, varscan2
- CAMK2D | chr4:113761468 A>G | 5'Flank (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- CERS6 | c.*3095G>A | 3'UTR (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- CLLU1 | n.539C>T | RNA (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- CLMP | c.-70T>C | 5'UTR (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- CPT2 | c.*326C>A | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- CSPG5 | c.-1314A>C | 5'UTR (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- DDX55 | c.*90C>T | 3'UTR (SNP) | VAF 63/127 reads (50%) | called by muse, mutect2, varscan2
- DLGAP2 | c.*3260G>A | 3'UTR (SNP) | VAF 14/18 reads (78%) | called by muse, mutect2, varscan2
- E2F7 | c.*2490A>G | 3'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as COSV59742805; called by muse, mutect2, varscan2
- ERV3-1 | c.-359T>A | 5'UTR (SNP) | VAF 92/146 reads (63%) | called by muse, mutect2, varscan2
- EVL | c.-118G>A | 5'UTR (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- FUNDC2 | c.*3315C>A | 3'UTR (SNP) | VAF 53/206 reads (26%) | called by muse, mutect2, varscan2
- FXYD6 | c.*143C>A | 3'UTR (SNP) | VAF 51/131 reads (39%) | catalogued as COSV52804530; called by muse, mutect2, varscan2
- GBA2 | c.-197C>T | 5'UTR (SNP) | VAF 15/61 reads (25%) | catalogued as rs918078715; called by mutect2, varscan2
- GTF2F1 | c.*145C>T | 3'UTR (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- HADH | c.637-41G>T | Intron (SNP) | VAF 38/96 reads (40%) | called by muse, mutect2, varscan2
- HEPH | c.*35T>A | 3'UTR (SNP) | VAF 76/172 reads (44%) | called by muse, mutect2, varscan2
- HES6 | chr2:238240647 C>T | 5'Flank (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- HS1BP3 | c.623+1009G>A | Intron (SNP) | VAF 108/192 reads (56%) | catalogued as rs1472933256; called by muse, mutect2, varscan2
- IDO2 | c.449+60A>T | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- KRT19 | c.421-47A>T | Intron (SNP) | VAF 43/137 reads (31%) | called by muse, mutect2, varscan2
- LDOC1 | c.*322C>A | 3'UTR (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- MAGIX | chrX:49167732 T>C | 3'Flank (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- MECP2 | c.*8676T>C | 3'UTR (SNP) | VAF 68/102 reads (67%) | called by muse, varscan2
- MYO1E | c.-139C>T | 5'UTR (SNP) | VAF 70/304 reads (23%) | called by muse, varscan2
- NDUFA9 | c.*1068G>A | 3'UTR (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- NHLH2 | c.-9+905C>T | Intron (SNP) | VAF 10/65 reads (15%) | called by mutect2, varscan2
- NKTR | c.1018-119A>C | Intron (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2, varscan2
- OLFM1 | c.*98T>A | 3'UTR (SNP) | VAF 48/153 reads (31%) | called by muse, mutect2, varscan2
- PARD6G | c.296-8498G>T | Intron (SNP) | VAF 33/73 reads (45%) | catalogued as rs568444001; called by muse, mutect2, varscan2
- PCBP2P2 | n.880G>C | RNA (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-12416C>T | Intron (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.*767C>T | 3'UTR (SNP) | VAF 49/137 reads (36%) | called by muse, mutect2, varscan2
- PPM1L | c.*6080A>G | 3'UTR (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- S1PR2 | c.-43+722C>T | Intron (SNP) | VAF 68/308 reads (22%) | catalogued as rs571967599, COSV73912781; called by muse, varscan2
- SGCD | c.*6076C>A | 3'UTR (SNP) | VAF 13/19 reads (68%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.*1372A>G | 3'UTR (SNP) | VAF 43/131 reads (33%) | called by muse, mutect2, varscan2
- SPINK1 | c.-11G>T | 5'UTR (SNP) | VAF 72/113 reads (64%) | called by muse, mutect2, varscan2
- STAU2 | chr8:73420222 G>T | 3'Flank (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- TMEM44 | c.*799G>A | 3'UTR (SNP) | VAF 7/124 reads (6%) | called by muse, mutect2
- TMSB4X | chrX:12975615 G>A | 5'Flank (SNP) | VAF 124/292 reads (42%) | catalogued as rs772005522, COSV66081743; called by muse, mutect2, varscan2
- TMSB4X | c.-16-131A>T | Intron (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- TRIP11 | c.*1398G>A | 3'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- TRPC1 | c.*1431A>T | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- UBE2F | c.*17C>T | 3'UTR (SNP) | VAF 57/142 reads (40%) | called by muse, mutect2, varscan2
- UBP1 | c.-77-165C>T | Intron (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- USP22 | c.*3292A>G | 3'UTR (SNP) | VAF 26/90 reads (29%) | catalogued as rs1374619271; called by muse, mutect2, varscan2
- WNT9A | c.*1097A>T | 3'UTR (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- ZDHHC3 | c.*11109_*11136del | 3'UTR (DEL) | VAF 39/231 reads (17%) | called by mutect2, varscan2
- ZNF439 | c.*257G>T | 3'UTR (SNP) | VAF 20/101 reads (20%) | catalogued as rs1010439299; called by muse, mutect2, varscan2
